Gene-level copy-number profile of tumor specimen CDDP-ACR8-TTP1-A from CDDP_EAGLE case CDDP-ACR8, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 59 years.
Specimen CDDP-ACR8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7915d891-562f-4cc7-995f-f53cc820998e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ACR8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,777 have no estimate.
https://portal.gdc.cancer.gov/files/2876ea43-18d8-4559-b89e-d01f2a5d292e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 668; copy number 1: 12,640; copy number 2: 38,769; copy number 3: 5,053; copy number 4: 1,514; copy number 5: 160; copy number 6: 19; copy number 7: 13; copy number 8: 4; copy number 9: 3; copy number 10: 2; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 156 genes in 55 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,324,756–1,349,418, 4 genes: CPTP, TAS1R3, DVL1, MIR6808.
- chr1:1,434,861–1,442,882, 1 gene: VWA1.
- chr1:1,534,778–1,540,624, 1 gene: TMEM240.
- chr1:2,019,329–2,050,070, 2 genes: GABRD, AL391845.1.
- chr1:2,492,300–2,494,479, 2 genes (within-gene range 0–1): AL139246.1, AL139246.4.
- chr1:2,566,410–2,591,469, 3 genes (within-gene range 0–1): AL139246.2, AL139246.3, PRXL2B.
- chr1:3,021,467–3,611,508, 13 genes (within-gene range 0–1): ACTRT2, PRDM16-DT, PRDM16, MIR4251, AL008733.1, AL512383.1, AL590438.1, AL354743.2, AL354743.1, ARHGEF16, AL512413.1, MEGF6, MIR551A.
- chr1:5,862,672–5,862,741, 1 gene: MIR4689.
- chr4:54,603,211–54,740,715, 2 genes: LINC02260, KIT.
- chr4:186,890,969–186,900,838, 3 genes: AC108865.1, AC108865.2, MRPS36P2.
- chr6:3,268,962–3,457,050, 2 genes (within-gene range 0–1): SLC22A23, AL445309.1.
- chr6:29,475,025–29,749,049, 22 genes (within-gene range 0–1): MAS1LP1, MAS1L, RPS17P1, LINC02829, LINC01015, GPR53P, OR2I1P, UBD, GABBR1, OR2H5P, TMEM183AP1, SNORD32B, RPL13AP, OR2H2, SUMO2P1, MOG, ZFP57, ZDHHC20P1, HLA-F, AL645939.1, HLA-F-AS1, RPL23AP1.
- chr7:192,571–260,772, 2 genes (within-gene range 0–1): FAM20C, AC145676.1.
- chr8:141,389,939–141,432,454, 2 genes: AC100803.2, PTP4A3.
- chr9:134,293,931–134,300,413, 2 genes: LINC02247, AL354796.1.
- chr9:134,849,298–135,121,180, 13 genes: MIR3689C, MIR3689A, MIR3689D1, MIR3689B, MIR3689D2, MIR3689E, MIR3689F, AL603650.1, FCN2, FCN1, AL353611.1, AL353611.2, OLFM1.
- chr9:136,249,973–136,359,605, 4 genes (within-gene range 0–1): CCDC187, CR392000.1, DKFZP434A062, GPSM1.
- chr9:136,542,881–136,549,893, 3 genes (within-gene range 0–1): AL592301.1, MIR4674, NALT1.
- chr10:128,912,810–128,916,429, 1 gene: LINC02667.
- chr11:69,371,463–69,372,512, 1 gene: AP005233.2.
- chr14:104,769,349–104,795,751, 2 genes (within-gene range 0–1): AL583722.1, AKT1.
- chr16:788,046–800,737, 2 genes (within-gene range 0–1): CHTF18, GNG13.
- chr16:898,967–905,224, 1 gene (within-gene range 0–1): AL008727.1.
- chr16:991,151–1,096,244, 5 genes (within-gene range 0–1): AC009041.1, SSTR5-AS1, AC009041.2, SSTR5, C1QTNF8.
- chr16:1,431,078–1,446,519, 4 genes (within-gene range 0–2): PERCC1, CCDC154, AL032819.2, AL031600.3.
- chr16:88,856,220–88,977,207, 6 genes (within-gene range 0–1): TRAPPC2L, PABPN1L, CBFA2T3, AC092384.2, AC092384.3, AC092384.1.
- chr17:6,643,311–6,651,634, 1 gene (within-gene range 0–1): MED31.
- chr17:6,653,464–6,655,509, 3 genes: AC004706.1, MIR4520-1, MIR4520-2.
- chr17:15,229,773–15,272,292, 2 genes (within-gene range 0–2): PMP22, MIR4731.
- chr17:18,411,159–18,418,306, 2 genes: LINC02076, YWHAEP2.
- chr17:18,450,244–18,475,920, 4 genes: KRT16P4, AL353997.1, AL353997.4, TNPO1P2.
- chr17:18,497,095–18,551,705, 4 genes (within-gene range 0–1): NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr17:19,020,656–19,047,011, 2 genes (within-gene range 0–1): GRAP, AC003957.1.
- chr17:20,784,645–20,785,725, 1 gene: SCDP1.
- chr19:797,075–812,327, 2 genes: PTBP1, MIR4745.
- chr19:2,163,933–2,248,655, 4 genes (within-gene range 0–2): DOT1L, AC004490.1, MIR6789, SF3A2.
- chr20:62,708,836–62,762,771, 2 genes: NTSR1, AL357033.2.
- chr20:63,218,041–63,272,694, 5 genes: AL096828.3, BIRC7, MIR3196, NKAIN4, FLJ16779.
- chr20:63,540,810–63,556,695, 3 genes: SRMS, AL121829.2, FNDC11.
- chr21:44,989,864–44,995,185, 2 genes: LINC00163, LINC00165.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 202 genes in 51 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:28,668,778–28,719,353, 2 genes, copy number 5: GMEB1, AL645729.1.
- chr3:153,067,278–153,129,640, 2 genes, copy number 5: HMGN2P13, AC117394.1.
- chr3:163,026,396–163,361,563, 3 genes, copy number 5: AC128685.1, LINC01192, RPS6P4.
- chr3:172,750,682–172,821,474, 3 genes, copy number 5: ECT2, SNORA72, RNU4-4P.
- chr3:185,476,496–185,825,042, 7 genes, copy number 5 (within-gene range 4–5): TMEM41A, LIPH, SENP2, AC133473.1, IGF2BP2, IGF2BP2-AS1, MIR548AQ.
- chr3:196,142,525–196,736,007, 32 genes, copy number 5: LINC00885, ZDHHC19, Y_RNA, SLC51A, PCYT1A, AC069257.3, AC069257.1, TCTEX1D2, AC069257.2, TM4SF19-TCTEX1D2, TM4SF19-AS1, TM4SF19, RNU6-910P, UBXN7, RNU6-1279P, RN7SL434P, RN7SL738P, AC083822.1, UBXN7-AS1, AC117490.1, RNF168, AC117490.2, SMCO1, AC092933.1, RPS29P3, WDR53, FBXO45, LINC01063, NRROS, PIGX, CEP19, RNU6-646P.
- chr5:10,337,277–10,343,131, 2 genes, copy number 5: Y_RNA, AC012640.5.
- chr6:42,746,958–43,075,095, 21 genes, copy number 5: BICRAL, RPL7L1, C6orf226, PTCRA, AL035587.2, CNPY3, AL035587.1, RPL24P4, GNMT, PEX6, PPP2R5D, MEA1, KLHDC3, RRP36, AL136304.1, RN7SL403P, CUL7, KLC4, AL355385.2, MRPL2, AL355385.1.
- chr7:74,231,499–74,405,935, 2 genes, copy number 5: RFC2, CLIP2.
- chr7:75,810,825–75,888,926, 3 genes, copy number 5: CCL24, AC005102.1, RHBDD2.
- chr7:76,389,334–76,516,522, 6 genes, copy number 5–7 (within-gene range 5–8): SSC4D, ZP3, DTX2, FDPSP2, AC005522.1, UPK3B.
- chr7:102,456,238–102,679,295, 14 genes, copy number 6–9 (within-gene range 1–13): ALKBH4, LRWD1, MIR5090, MIR4467, POLR2J, RASA4B, POLR2J3, UPK3BL2, AC093668.1, SPDYE2, POLR2J3, RASA4, AC105052.4, AC105052.1.
- chr7:138,404,195–138,442,238, 2 genes, copy number 5: PTMAP10, IMPDH1P3.
- chr7:139,448,740–139,544,985, 5 genes, copy number 5: RNU6-911P, KLRG2, AC005531.1, CLEC2L, ERHP1.
- chr7:140,435,316–140,479,536, 2 genes, copy number 5: AC069335.1, MKRN1.
- chr7:149,053,961–149,183,042, 5 genes, copy number 6: COX6B1P1, ZNF786, ZNF425, RN7SL521P, ZNF398.
- chr7:152,602,213–152,757,951, 5 genes, copy number 5: AC104843.1, AC003109.1, XRCC2, ATP5PBP3, RN7SL845P.
- chr10:68,717,311–68,717,795, 1 gene, copy number 7: AL513534.3.
- chr10:73,625,996–73,675,450, 5 genes, copy number 5 (within-gene range 1–5): AC073389.1, AC073389.3, MYOZ1, SYNPO2L, AC073389.2.
- chr12:122,726,076–122,730,844, 1 gene, copy number 5: HCAR1.
- chr16:32,250,620–32,255,922, 2 genes, copy number 8: AC133485.3, TP53TG3D.
- chr16:32,439,069–32,441,159, 1 gene, copy number 5: PABPC1P13.
- chr16:32,600,299–32,615,639, 1 gene, copy number 5: AC137800.1.
- chr16:32,715,931–32,824,645, 10 genes, copy number 5–7: AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10, AC137761.1, AC137761.2.
- chr16:33,808,778–33,810,767, 1 gene, copy number 8: AC136428.3.
- chr16:33,857,935–33,859,352, 2 genes, copy number 5: AC140658.2, IGHV3OR16-11.
- chr16:33,907,419–33,937,167, 1 gene, copy number 5: ARHGAP23P1.
- chr17:18,476,737–18,494,945, 1 gene, copy number 8: LGALS9C.
- chr17:20,501,513–20,512,357, 2 genes, copy number 10: KRT16P3, AC015818.7.
- chr17:27,237,859–27,241,661, 1 gene, copy number 5: AC129926.1.
- chr17:61,865,367–62,140,639, 9 genes, copy number 5: INTS2, Y_RNA, MED13, AC018628.1, RN7SL800P, AC018628.2, Y_RNA, Y_RNA, POLRMTP1.
- chr17:62,423,875–62,453,385, 1 gene, copy number 5: METTL2A.
- chr17:66,212,033–66,267,848, 2 genes, copy number 5: APOH, RNA5SP444.
- chr17:67,268,110–67,366,605, 4 genes, copy number 5: RNA5SP447, AC007448.1, AC007448.2, PSMD12.
- chr17:67,774,591–67,785,293, 2 genes, copy number 6: RPSAP67, RPL17P41.
- chr17:75,087,727–75,235,758, 11 genes, copy number 5: SLC16A5, Y_RNA, ARMC7, NT5C, AC022211.4, JPT1, AC022211.3, AC022211.1, Y_RNA, SUMO2, NUP85.
- chr17:75,751,594–75,825,799, 4 genes, copy number 5 (within-gene range 1–5): GALK1, H3-3B, MIR4738, UNK.
- chr17:76,274,049–76,384,521, 5 genes, copy number 5 (within-gene range 4–5): QRICH2, PRPSAP1, Y_RNA, RNU6-24P, AC090699.1.
- chr19:17,226,213–17,282,966, 6 genes, copy number 5 (within-gene range 3–5): OCEL1, NR2F6, AC010646.1, USHBP1, BABAM1, AC010463.1.
- chr19:27,638,483–27,646,483, 2 genes, copy number 5: ERVK-28, AC112702.1.

Autosomal genes at a single copy (total copy number 1): 10,303. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
